Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4868, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4868-01A (Primary Tumor).

Pathology Report
DIAGNOSIS

(A) HILAR LYMPH NODE:

Eleven lymph nodes negative for tumor (0/11).

(B) LEFT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN'S NUCLEAR GRADE 3 (9.0 X 0.5 X 8.0 CM).

TUMOR GROSSLY INVOLVES HILAR VEIN.

Multifocal microscopic extension to perinephric adipose tissue.

Hilar resection margin (vascular and ureteral) are free of tumor.

SATELLITE NODULE OF RENAL CELL CARCINOMA IN ADJACENT RENAL PARENCHYMA (0.4 X 0.4 X 0.4 CM).

METASTATIC RENAL CELL CARCINOMA IN ADRENAL GLAND (1.1 X 0.9 X 0.7 CM).

(C) ADDITIONAL HILAR LYMPH NODES:

Three lymph nodes negative for tumor (0/3).

GROSS DESCRIPTION

(A) HILAR LYMPH NODE - A portion of soft lobulated fibroadipose tissue measures 8.0 x 3.0 x 0.8 cm. It contains multiple possible red-purple smooth lymph node up to 2.5 x 1.5 x 0.4 cm.

SECTION CODE: A1-A2, one node serially sectioned; A3, one node bisected; A4, one node bisected; A5, one node bisected; A6, three possible nodes; A7, five possible nodes.

(B) LEFT KIDNEY - A left nephrectomy specimen measuring 26.0 x 15.0 x 7.5 cm includes an adrenal gland measuring 7.0 x 3.0 x 1.0 cm, which contains a soft tan tumor (1.8 x 1.0 x 1.0 cm).

Located within the mid superior pole of the kidney, a heterogeneous, solid and cystic, gray-white to yellow and hemorrhagic tumor (9.0 x 8.5 x 8.0 cm) fills the renal pelvis and extends into the renal vein. The tumor is not present at the venous margin. The tumor focally is adjacent to renal parenchyma without extension to the renal capsule.

A satellite tumor nodule (0.4 x 0.4 x 0.4 cm) is gray-white, well-circumscribed and located in the cortex, 0.3 cm from the capsule surface. The remainder of the renal parenchyma is homogeneous brown.

The adrenal gland shows a well-circumscribed yellowish nodule measuring 1.1 x 0.9 x 0.7 cm.

SECTION CODE: B1, vascular margin; B2, tumor within renal vein; B3-B4, adrenal metastasis; B5, separate tumor nodule in cortex; B6-B11, tumor within the renal pelvis abutting soft tissue; B12-B14, tumor adjacent to renal cortex; B15, tumor; B16, normal renal parenchyma.

(C) ADDITIONAL HILAR LYMPH NODE - A portion of lobulated fibroadipose tissue measures 1.5 x 1.0 x 0.5 cm and contains three possible lymph nodes up to 1.1 x 0.8 x 0.3 cm.

SECTION CODE: C, three possible lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-3123

Source: NCI Genomic Data Commons file ac69c65e-cf66-4a7e-9a9e-1983b5d86d13 (TCGA-CJ-4868.79DA436E-DD72-4823-92CC-25D002BB4B90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).